Surgical pathology report (de-identified scan), TCGA case TCGA-XV-AAZY, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site  Capital Biosciences, specimen TCGA-XV-AAZY-01A (Primary Tumor).

Pathology Report

Date:

Patient ID:

Age:

Sex:

F

Clinical Dx:

Melanoma

Tumor Location:

Skin

Localization:

Abdominal wall

Source:

Epithelial melanoma

Clark Level (1-5):

5

Breslow (mm):

16

Tumor:

4

Normal:

3

Metastasis:

0

Stage (I-IV):

3

Tumor size (mm x mm):

15x12

NeoAdj ImmunoTx:

No

ICD 03
Melanoma NOS 8720/3
Site: Abdominal wall
144.5
W3/12/14

Source: NCI Genomic Data Commons file d6ae4078-d368-4622-a9ba-3c72591ffb05 (TCGA-XV-AAZY.D775C305-10CA-4545-8352-EA87BCAB8304.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).